Somatic mutation profile of tumor specimen TCGA-E7-A97P-01A (aliquot TCGA-E7-A97P-01A-11D-A38G-08) from TCGA case TCGA-E7-A97P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 73.8 years (26,956 days).
Specimen TCGA-E7-A97P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12ff1879-94af-427e-b9ce-6ef392b6d012.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A97P-10A (Blood Derived Normal), aliquot TCGA-E7-A97P-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfb396d2-5769-471a-a1d6-829067014bc2

The open-access MAF lists 233 somatic variants for this specimen: 179 protein-altering or splice-affecting, 49 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 49, Nonsense Mutation 13, Frame Shift Del 7, Splice Site 5, In Frame Del 4, Frame Shift Ins 3, Intron 2, RNA 2, Splice Region 1, 5'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC2 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55538701; called by muse, mutect2, varscan2
- HRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.1733C>G p.P578R (on ENST00000372530 / NM_001198934.2; = p.P535R on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.96); catalogued as COSV55085203, COSV55085279; called by muse, mutect2, varscan2
- ABI3BP | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); catalogued as COSV52530679, COSV99425310; called by muse, mutect2, varscan2
- ACAP1 | c.944G>A p.C315Y | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50134257; called by muse, mutect2, varscan2
- ADAMTS16 | c.1830T>G p.S610R | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV56980787, COSV56988650; called by muse, mutect2, varscan2
- ADAMTS4 | c.1028G>C p.R343P | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs372130629, COSV63487407; called by muse, mutect2, varscan2
- ADGRD1 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55440192; called by muse, mutect2, varscan2
- AKNA | c.3502C>T p.R1168* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as rs765932672, COSV99799611, COSV99801305; called by muse, mutect2, varscan2
- AL031777.2 | c.340G>C p.A114P | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as COSV61911625; called by muse, mutect2, varscan2
- AL136295.1 | c.1196A>G p.D399G | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.498); catalogued as COSV55778480; called by muse, mutect2, varscan2
- ALDOC | c.558T>G p.I186M | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV52023838; called by muse, mutect2, varscan2
- AMN1 | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.205); catalogued as COSV55670526; called by muse, mutect2, varscan2
- AREL1 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV62665650; called by muse, mutect2
- ARHGAP10 | c.2302G>T p.E768* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100330870; called by muse, mutect2, varscan2
- ARHGAP32 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV100086835; called by muse, mutect2
- ARHGAP33 | c.530T>A p.L177H | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as COSV50119923; called by muse, mutect2, varscan2
- ARMCX2 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100168042, COSV100168314, COSV57529376; called by muse, mutect2, varscan2
- ARNT | c.1637A>G p.D546G | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as COSV62229910; called by muse, mutect2, varscan2
- ATP6AP1 | c.1351A>C p.K451Q | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV63895346; called by muse, mutect2, varscan2
- C1QL3 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs1211686082, COSV54348096; called by muse, mutect2, varscan2
- CABLES1 | c.1659A>T p.K553N (on ENST00000256925 / NM_001100619.2; = p.K288N on NM_138375.2) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs372087098, COSV56931128; called by muse, mutect2, varscan2
- CAMK2A | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); catalogued as COSV62245362, COSV62246303; called by muse, mutect2, varscan2
- CAMK2B | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV51657932; called by muse, mutect2, varscan2
- CARD6 | c.1630G>T p.G544C | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54564570; called by muse, mutect2, varscan2
- CD1D | c.672C>A p.C224* | Nonsense Mutation (SNP) | VAF 29/127 reads (23%) | catalogued as COSV100939538; called by muse, mutect2, varscan2
- CDH23 | c.9617G>C p.R3206P | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99818761; called by muse, mutect2, varscan2
- CDIN1 | c.762G>C p.E254D (on ENST00000437989; = p.E156D on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV57710109; called by muse, mutect2, varscan2
- CEP126 | c.3275C>A p.S1092Y | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1182223642, COSV54822342; called by muse, mutect2, varscan2
- COBLL1 | c.2980C>T p.P994S (on ENST00000392717; = p.P956S on NM_014900.5) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.074); catalogued as COSV52070838, COSV99528755; called by muse, mutect2
- COQ8B | c.82G>C p.G28R | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as COSV54573569; called by muse, mutect2, varscan2
- CPD | c.3616A>T p.S1206C | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56711209; called by muse, mutect2, varscan2
- DCDC2 | c.1233G>T p.E411D | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV65828419; called by muse, mutect2, varscan2
- DNAH7 | c.3398C>T p.T1133I | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56754688; called by muse, mutect2, varscan2
- DOCK11 | c.3917C>T p.S1306L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.313); catalogued as rs1252227645, COSV52234859; called by muse, mutect2, varscan2
- EEA1 | c.1364T>C p.V455A | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.97); catalogued as rs1400365329, COSV59283212; called by muse, mutect2, varscan2
- EPC1 | c.1939G>C p.V647L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.043); catalogued as COSV53923569; called by muse, mutect2, varscan2
- EPHA3 | c.311G>C p.R104P | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60696515, COSV60700528; called by muse, mutect2, varscan2
- F2RL1 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1052875957, COSV56995117; called by muse, mutect2, varscan2
- FAM135B | c.1076T>G p.L359R | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.095); catalogued as COSV52709678, COSV52718533; called by muse, mutect2, varscan2
- FANCA | c.4077C>G p.D1359E | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.659); catalogued as COSV57066439; called by muse, mutect2, varscan2
- FBXL4 | c.1257C>G p.F419L | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV57745331; called by muse, mutect2, varscan2
- FBXL7 | c.1162G>T p.G388C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV61642183; called by muse, mutect2, varscan2
- FER1L6 | c.1080T>A p.F360L | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV67548460; called by muse, mutect2, varscan2
- FERMT3 | c.1744G>C p.D582H (on ENST00000279227 / NM_178443.3; = p.D578H on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54172420; called by muse, mutect2, varscan2
- FHL1 | c.265T>C p.C89R | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61779979; called by muse, mutect2, varscan2
- FKBP6 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as rs781881868, COSV99333678; called by muse, mutect2, varscan2
- FLII | c.2399C>T p.A800V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57496555; called by muse, mutect2, varscan2
- FOSL1 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.107); catalogued as COSV57027557; called by muse, mutect2, varscan2
- FRMD4A | c.1154A>G p.K385R | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.405); catalogued as COSV52716470; called by muse, mutect2, varscan2
- FST | c.130G>T p.V44F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.344); catalogued as rs893682575, COSV56815030, COSV99887367; called by muse, mutect2, varscan2
- GCC2 | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV59174455; called by muse, mutect2, varscan2
- GNL3L | c.1012A>G p.I338V | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.456); catalogued as COSV60575573; called by muse, mutect2, varscan2
- GTF2H3 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 35/117 reads (30%) | catalogued as rs1366954614, COSV99967481; called by muse, mutect2, varscan2
- HBP1 | c.1035T>A p.F345L | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as COSV56017080; called by muse, mutect2, varscan2
- HECW2 | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs1057520120, COSV53651678; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HELB | c.946A>G p.N316D | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56072513; called by muse, mutect2, varscan2
- HIP1 | c.2039C>T p.A680V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV61183766; called by muse, mutect2, varscan2
- HOXA2 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV56065396; called by muse, mutect2, varscan2
- HOXD1 | c.848A>G p.K283R | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553528002, COSV58923197; called by muse, mutect2, varscan2
- ISM1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373498255; called by muse, mutect2, varscan2
- ITPR2 | c.5183-2A>G p.X1728_splice | Splice Site (SNP) | VAF 10/29 reads (34%) | catalogued as rs1377741310, COSV67265941; called by muse, mutect2, varscan2
- KHNYN | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs979523567, COSV52158789; called by muse, mutect2, varscan2
- KHSRP | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67919413; called by muse, mutect2, varscan2
- KIF5A | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54052178; called by muse, mutect2, varscan2
- LIMA1 | c.289_308del p.I97Sfs*4 | Frame Shift Del (DEL) | VAF 18/134 reads (13%) | catalogued as COSV57964278; called by mutect2, pindel
- LMF2 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV99327371; called by muse, mutect2
- LMTK2 | c.1790T>C p.L597P | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as COSV51991781; called by muse, mutect2, varscan2
- LRRC7 | c.3127G>T p.D1043Y (on ENST00000651989 / NM_001370785.2; = p.D1010Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50418052; called by muse, mutect2, varscan2
- LY75 | c.1337A>G p.Y446C | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1259460452, COSV55102685; called by muse, mutect2, varscan2
- MCM4 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50621606; called by muse, mutect2, varscan2
- MEIOB | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.496); catalogued as COSV58053190; called by muse, mutect2, varscan2
- MIS18BP1 | c.1174A>G p.S392G | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV60369433; called by muse, mutect2, varscan2
- MLX | c.703G>C p.D235H | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53816397; called by muse, mutect2
- MPI | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60396430; called by muse, mutect2, varscan2
- MPPED2 | c.310G>C p.G104R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as COSV63896501; called by muse, mutect2, varscan2
- MROH2B | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.137); catalogued as rs1427712030, COSV101270924, COSV68181885, COSV68186148; called by muse, mutect2, varscan2
- MRPL37 | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60321150; called by muse, mutect2, varscan2
- MRPL49 | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV53694817; called by muse, mutect2, varscan2
- MTMR6 | c.1764C>A p.S588R | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV67807906; called by muse, mutect2, varscan2
- MYOZ3 | c.607G>T p.G203* | Nonsense Mutation (SNP) | VAF 9/79 reads (11%) | catalogued as COSV99770599; called by muse, mutect2, varscan2
- MYT1 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV60501936; called by muse, mutect2, varscan2
- NAA15 | c.1177G>T p.A393S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV56717945; called by mutect2, varscan2
- NAA15 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56717957; called by mutect2, varscan2
- NBPF3 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV59057292, COSV59058997; called by muse, mutect2, varscan2
- NCCRP1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as rs759181864, COSV59212284; called by muse, mutect2, varscan2
- NDUFAF7 | c.1166A>G p.Y389C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV50016998; called by muse, mutect2, varscan2
- NPL | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV51122773; called by muse, mutect2, varscan2
- NR1D2 | c.1736C>G p.P579R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56990926; called by muse, mutect2, varscan2
- NUMA1 | c.6314C>T p.A2105V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1368647971, COSV99474477; called by muse, mutect2, varscan2
- NUP160 | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65853745; called by muse, mutect2, varscan2
- OR56A4 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs748087343, COSV58109480; called by muse, mutect2, varscan2
- OR56B4 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV57204102; called by muse, mutect2, varscan2
- OSER1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs750973244, COSV54853301; called by muse, varscan2
- OSER1 | c.370T>C p.S124P | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54853313; called by muse, varscan2
- PC | c.3079T>G p.F1027V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV58992209; called by muse, mutect2, varscan2
- PCDH9 | c.3714A>C p.*1238Yext*26 (on ENST00000377865 / NM_203487.3; = p.*1204Yext*26 on NM_020403.5 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV60531117, COSV60535317, COSV60559707; called by muse, mutect2, varscan2
- PCDHGA4 | c.2200G>A p.V734I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.037); catalogued as rs764785344, COSV53909981; called by muse, mutect2, varscan2
- PDE12 | c.1396A>G p.I466V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.823); catalogued as rs763230699, COSV60818164; called by muse, mutect2
- PDZD2 | c.7820T>C p.I2607T | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs1242164112, COSV56852661; called by muse, mutect2, varscan2
- PFKFB3 | c.321G>T p.L107F | Missense Mutation (SNP) | VAF 23/146 reads (16%) | PolyPhen probably damaging (0.991); catalogued as COSV57987249, COSV57991530; called by muse, mutect2, varscan2
- PHLDA3 | c.316A>T p.K106* | Nonsense Mutation (SNP) | VAF 22/104 reads (21%) | catalogued as COSV100943585; called by muse, mutect2, varscan2
- PITPNM2 | c.2374C>G p.P792A | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54896980; called by muse, mutect2, varscan2
- PKD2 | c.2358G>A p.R786= | Splice Region (SNP) | VAF 9/50 reads (18%) | catalogued as rs1375334614, COSV52936976; called by muse, mutect2, varscan2
- PKHD1 | c.2765C>G p.S922C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV61863790, COSV61871241; called by muse, mutect2, varscan2
- PLD1 | c.1314G>T p.L438F | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60565947; called by muse, mutect2, varscan2
- PLXNB2 | c.3428C>T p.T1143M | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs1443835685, COSV63780333; called by muse, mutect2, varscan2
- POU2AF1 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs754119748, COSV67576975; called by muse, varscan2
- PPP1R3A | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV52875965, COSV52877899; called by muse, mutect2, varscan2
- PRKCG | c.914G>T p.C305F | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV54724731; called by muse, mutect2, varscan2
- PRKG1 | c.1513C>G p.L505V | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV64767295, COSV64771514; called by muse, mutect2, varscan2
- PTPN4 | c.192G>T p.L64F | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1351098041, COSV55298445; called by muse, mutect2, varscan2
- RAD51AP2 | c.1760dup p.L587Ffs*4 | Frame Shift Ins (INS) | VAF 17/85 reads (20%) | catalogued as rs781047879; called by mutect2, pindel, varscan2
- RARRES1 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs781666181, COSV52961697; called by muse, mutect2, varscan2
- RBBP6 | c.4120C>G p.Q1374E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as rs1464331759, COSV60503719; called by muse, mutect2, varscan2
- REM1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1397404738, COSV52426654; called by muse, mutect2, varscan2
- RGS22 | c.3095C>T p.S1032L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV62658290; called by muse, mutect2, varscan2
- RILPL1 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV65300938; called by muse, mutect2, varscan2
- RPRD2 | c.1714A>G p.T572A | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs777781351, COSV64818893; called by muse, mutect2, varscan2
- RYR1 | c.4700A>G p.K1567R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.418); catalogued as rs755755514, COSV100614383; called by muse, mutect2
- SCN1B | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52893588; called by muse, mutect2, varscan2
- SEC31A | c.2782G>T p.A928S (on ENST00000355196 / NM_001318120.1; = p.A889S on NM_016211.4) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs142882690, COSV52354771; called by muse, varscan2
- SEPTIN14 | c.614A>G p.Q205R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); catalogued as COSV66426463; called by muse, mutect2, varscan2
- SFPQ | c.1411C>T p.Q471* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100599277; called by mutect2, varscan2
- SFSWAP | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs200555358, COSV55520169; called by muse, mutect2, varscan2
- SFSWAP | c.1495T>C p.Y499H | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs953369508, COSV55520179; called by muse, mutect2, varscan2
- SIPA1L2 | c.2393G>T p.R798L | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as COSV53384792; called by muse, mutect2, varscan2
- SLC25A25 | c.862_873del p.S288_G291del | In Frame Del (DEL) | VAF 35/127 reads (28%) | catalogued as rs779327899; called by mutect2, varscan2
- SLC26A9 | c.202A>G p.K68E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61601200; called by muse, mutect2, varscan2
- SLC46A3 | c.1012G>C p.G338R | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57180493; called by muse, mutect2, varscan2
- SLC5A7 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV50889417; called by muse, mutect2, varscan2
- SLURP1 | c.266A>G p.H89R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.125); catalogued as COSV55815889; called by muse, mutect2, varscan2
- SOD1 | c.11A>G p.K4R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV54255662; called by muse, mutect2, varscan2
- SPPL3 | c.808G>T p.G270* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as rs1410635191, COSV100793549; called by muse, mutect2, varscan2
- SPRY2 | c.682C>G p.H228D | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65701265; called by muse, mutect2, varscan2
- STAG2 | c.2327T>C p.L776P | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54352278; called by muse, mutect2, varscan2
- STAM | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV66324984; called by muse, mutect2, varscan2
- TARS1 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.282); catalogued as COSV54307783; called by muse, mutect2, varscan2
- TARS2 | c.495C>A p.F165L | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV64694673, COSV64696817; called by muse, mutect2, varscan2
- TEX9 | c.458C>G p.S153* | Nonsense Mutation (SNP) | VAF 26/110 reads (24%) | catalogued as rs139609954, COSV61880790; called by muse, mutect2, varscan2
- TGFBR1 | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM139800, COSV66624772, COSV66626929; called by muse, mutect2, varscan2
- TOMM40 | c.367A>C p.T123P | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV52976164; called by muse, mutect2, varscan2
- TPRG1L | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.059); catalogued as rs767432752, COSV54560287; called by muse, mutect2, varscan2
- TRAK1 | c.1024G>A p.E342K (on ENST00000327628 / NM_001349247.2; = p.E284K on NM_014965.5) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58256386; called by muse, mutect2
- TTC30B | c.1789A>G p.M597V | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV68809238; called by muse, mutect2, varscan2
- TTLL7 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as COSV99551801; called by muse, mutect2, varscan2
- TXLNG | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV66329479; called by muse, mutect2, varscan2
- UPF2 | c.3812_3816del p.R1271Mfs*10 | Frame Shift Del (DEL) | VAF 20/124 reads (16%) | catalogued as COSV62658782; called by mutect2, pindel, varscan2
- USF3 | c.5386C>G p.P1796A | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV57070437; called by muse, mutect2, varscan2
- USP54 | c.3064C>G p.Q1022E | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); catalogued as COSV60440300; called by muse, mutect2, varscan2
- UTP20 | c.5684G>C p.G1895A | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55373311; called by muse, mutect2, varscan2
- VAX2 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV52265239; called by muse, mutect2, varscan2
- VCAN | c.9035C>T p.P3012L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV54098721; called by muse, mutect2, varscan2
- VEGFC | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.186); catalogued as rs759656061, COSV54594678; called by muse, mutect2, varscan2
- VPS8 | c.643C>G p.L215V (on ENST00000625842 / NM_001349294.1; = p.L213V on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV54981407; called by muse, mutect2, varscan2
- WFDC8 | c.332G>A p.W111* | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | catalogued as COSV51491938, COSV99250257; called by muse, mutect2, varscan2
- XKR4 | c.387C>A p.D129E | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs1291386165, COSV59302747; called by muse, mutect2, varscan2
- YY1 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as rs1204309662, COSV99216652; called by muse, mutect2
- ZNF300 | c.305T>C p.L102S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.039); catalogued as COSV51032185; called by muse, mutect2, varscan2
- ZNF345 | c.941A>G p.Y314C | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770709729, COSV59322832; called by muse, mutect2, varscan2
- ZNF451 | c.1828A>G p.I610V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.224); catalogued as COSV62596756; called by muse, mutect2, varscan2
- ZNF461 | c.213G>C p.E71D | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.046); catalogued as rs1360252314, COSV100831350; called by muse, mutect2
- ZNF618 | c.2566G>T p.A856S (on ENST00000374126 / NM_001318042.2; = p.A763S on NM_133374.2) | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (0.75); PolyPhen benign (0.057); catalogued as COSV55917307; called by muse, mutect2, varscan2
- ZXDC | c.1016A>G p.Y339C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60445928; called by muse, mutect2, varscan2
- CAPZA1 | c.156-2_170del p.X52_splice | Splice Site (DEL) | VAF 19/139 reads (14%) | called by mutect2, pindel*
- CYB5B | c.176_199del p.X59_splice | Splice Site (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel
- DMXL1 | c.230del p.G77Efs*36 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- FCHO2 | c.2168_2170delinsT p.P723Lfs*17 | Frame Shift Del (DEL) | VAF 24/95 reads (25%) | called by pindel, varscan2*
- FOXQ1 | c.436_438del p.N146del | In Frame Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- GALNT5 | c.169_192del p.F57_G64del | In Frame Del (DEL) | VAF 32/153 reads (21%) | called by mutect2, pindel
- GRIK2 | c.2308_2311+19del p.X770_splice | Splice Site (DEL) | VAF 17/129 reads (13%) | called by mutect2, pindel
- MROH1 | c.2446C>G p.R816G | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- MRPS10 | c.37_48+2del p.X13_splice | Splice Site (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- OSBPL9 | c.1113dup p.K372Qfs*12 | Frame Shift Ins (INS) | VAF 17/126 reads (13%) | called by mutect2, pindel, varscan2
- PPP4R1 | c.2225_2243del p.Y742Wfs*2 (on ENST00000400556 / NM_001042388.3; = p.Y725Wfs*2 on NM_005134.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel
- PPP4R1 | c.819_839del p.E274_S280del (on ENST00000400556 / NM_001042388.3; = p.E257_S263del on NM_005134.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel
- PTGFRN | c.1483dup p.T495Nfs*46 | Frame Shift Ins (INS) | VAF 15/93 reads (16%) | called by mutect2, pindel, varscan2
- SORL1 | c.5746_5779del p.Q1916* | Frame Shift Del (DEL) | VAF 17/96 reads (18%) | called by mutect2, pindel
- SPPL3 | c.923del p.R308Pfs*17 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- A4GALT | c.861C>T p.I287= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99966585; called by muse, mutect2
- ACACA | c.4536C>G p.L1512= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1351026485; called by muse, mutect2, varscan2
- ACSL4 | c.216C>T p.D72= (on ENST00000340800 / NM_022977.2; = p.D31= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as COSV61613516; called by muse, mutect2, varscan2
- AMIGO2 | c.78G>A p.L26= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV56973475; called by muse, mutect2, varscan2
- ANK2 | c.522A>G p.G174= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs781072009, COSV52149520; called by muse, mutect2, varscan2
- APOB | c.4512T>C p.S1504= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV51926096; called by muse, mutect2, varscan2
- BHLHE23 | c.507C>T p.N169= (on ENST00000370346; = p.N185= on NM_080606.4) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1281491231, COSV100947576; called by muse, mutect2, varscan2
- BICC1 | c.930C>T p.I310= | Silent (SNP) | VAF 42/173 reads (24%) | catalogued as rs1184811864, COSV54062314; called by muse, mutect2, varscan2
- C1orf109 | c.486T>C p.S162= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV63656507; called by muse, mutect2, varscan2
- CDH16 | c.1893C>G p.T631= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV55335228; called by muse, mutect2, varscan2
- COQ3 | c.753T>C p.T251= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV54639202; called by muse, mutect2, varscan2
- CYP3A7 | c.711T>C p.N237= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV60480742; called by muse, mutect2, varscan2
- DCDC2 | c.468C>T p.L156= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as rs1274354012, COSV65831000; called by muse, mutect2, varscan2
- E2F6 | c.845G>A p.*282= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100215246; called by muse, mutect2, varscan2
- EML3 | c.729A>G p.P243= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs1421244637, COSV53881609; called by muse, mutect2, varscan2
- ERCC2 | c.1872C>G p.P624= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV67266969; called by muse, mutect2
- F2R | c.969C>T p.I323= | Silent (SNP) | VAF 5/85 reads (6%) | catalogued as COSV59928589; called by muse, mutect2
- GNA11 | c.255C>T p.T85= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs140204057, COSV50017662, COSV99312823; called by muse, mutect2, varscan2
- HRH1 | c.108T>G p.T36= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV67955122; called by muse, mutect2, varscan2
- HS3ST3A1 | c.531C>T p.D177= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs368104034; called by muse, mutect2
- INO80 | c.1941A>G p.Q647= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs758964021, COSV62736492; called by muse, mutect2, varscan2
- JAKMIP1 | c.372G>A p.A124= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs1185696215, COSV99288596; called by muse, mutect2
- KIAA2026 | c.4728A>G p.G1576= | Silent (SNP) | VAF 44/105 reads (42%) | catalogued as COSV67353613; called by muse, mutect2, varscan2
- KIF6 | c.2001G>A p.L667= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV54669173; called by muse, mutect2, varscan2
- KPNA4 | c.393A>G p.L131= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs1320639200, COSV62074853; called by muse, mutect2, varscan2
- MAP2 | c.1068C>A p.T356= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs1296160164, COSV52283507; called by muse, mutect2, varscan2
- MAP3K13 | c.2331A>G p.E777= | Silent (SNP) | VAF 38/188 reads (20%) | catalogued as COSV53984458; called by muse, mutect2, varscan2
- MED14 | c.879C>T p.Y293= | Silent (SNP) | VAF 46/114 reads (40%) | catalogued as rs1222446143, COSV61356065; called by muse, mutect2, varscan2
- MGA | c.3621A>G p.K1207= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as COSV54949978; called by muse, mutect2, varscan2
- MMP16 | c.912G>T p.P304= | Silent (SNP) | VAF 18/139 reads (13%) | catalogued as COSV54153682; called by muse, mutect2, varscan2
- MYCBP2 | c.11844A>G p.E3948= (on ENST00000357337; = p.E3986= on NM_015057.5) | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV62011899; called by muse, mutect2, varscan2
- NAGA | c.399C>T p.T133= | Silent (SNP) | VAF 36/169 reads (21%) | catalogued as COSV67169750; called by muse, mutect2, varscan2
- NIN | c.561G>A p.L187= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as rs1334173979, COSV55382223; called by muse, mutect2
- NLRP8 | c.1455C>A p.T485= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV52584258, COSV52584537; called by muse, mutect2, varscan2
- OR5W2 | c.75G>T p.V25= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV60614926; called by muse, mutect2, varscan2
- PDE5A | c.1506G>A p.G502= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV53345929; called by muse, mutect2, varscan2
- PDZD4 | c.2277C>G p.V759= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as COSV99381039; called by muse, mutect2, varscan2
- RAD54B | c.1167T>C p.D389= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100279350; called by muse, mutect2
- RBP3 | c.2559G>A p.E853= | Silent (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2
- SARDH | c.1209C>T p.F403= | Silent (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- SLC35G2 | c.579T>C p.N193= | Silent (SNP) | VAF 28/135 reads (21%) | catalogued as COSV67587913; called by muse, mutect2, varscan2
- STYXL2 | c.2517G>A p.K839= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV54802682; called by muse, mutect2, varscan2
- SYDE1 | c.2070C>A p.V690= | Silent (SNP) | VAF 53/178 reads (30%) | catalogued as COSV54618257; called by muse, mutect2, varscan2
- TM4SF20 | c.468T>A p.G156= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV58818501; called by muse, mutect2, varscan2
- TMF1 | c.2019C>T p.A673= | Silent (SNP) | VAF 32/149 reads (21%) | catalogued as rs936976804, COSV68373675; called by muse, mutect2, varscan2
- TTC7A | c.747G>C p.V249= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV55408870; called by muse, mutect2, varscan2
- USP15 | c.1329A>G p.K443= (on ENST00000280377 / NM_001351159.2; = p.K414= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs1565903604, COSV99738488; called by muse, mutect2, varscan2
- VPS13D | c.7335G>T p.V2445= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV50624793; called by muse, mutect2, varscan2
- VPS35L | c.2736C>G p.L912= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs765372304, COSV51978087; called by muse, mutect2, varscan2
- C3P1 | n.3249A>G | RNA (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- EXOC3 | chr5:442484 G>A | 5'Flank (SNP) | VAF 17/64 reads (27%) | catalogued as rs770480125; called by muse, mutect2, varscan2
- MIR508 | n.33G>A | RNA (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- RBMS1 | c.901-933A>C | Intron (SNP) | VAF 21/88 reads (24%) | catalogued as COSV100816997, COSV62351047; called by muse, mutect2, varscan2
- UAP1L1 | c.495-67G>A | Intron (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100814402; called by muse, mutect2, varscan2
